Gene-level copy-number profile of specimen HCM-BROD-0578-C15-85M from HCMI case HCM-BROD-0578-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 46.7 years (17,054 days).
Specimen HCM-BROD-0578-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe0ad73d-73f8-42fd-b7fd-d34b8bc37d4a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0578-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/42b885b8-9217-46dc-a32a-b01696c74327

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,075; copy number 2: 45,940; copy number 3: 3,068; copy number 4: 434; copy number 5: 50; copy number 7: 4; copy number 8: 7; copy number 9: 2; copy number 10: 10; copy number 11: 19; copy number 12: 24; copy number 13: 89; copy number 14: 9; copy number 15: 32; copy number 16: 6; copy number 17: 3; copy number 18: 8; copy number 20: 77; copy number 21: 3; copy number 22: 32; copy number 23: 12; copy number 24: 5; copy number 25: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 396 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:58,394,596–58,395,138, 1 gene, copy number 5: AC025578.1.
- chr12:59,322,765–59,789,855, 7 genes, copy number 5 (within-gene range 4–5): AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7.
- chr12:62,260,338–62,417,431, 4 genes, copy number 5 (within-gene range 4–5): USP15, MIR6125, RNU6-595P, Metazoa_SRP.
- chr12:62,601,751–62,622,213, 4 genes, copy number 5: LINC01465, AC048341.1, MIRLET7I, AC048341.2.
- chr12:65,278,643–65,491,430, 1 gene, copy number 8 (within-gene range 4–8): MSRB3.
- chr12:65,418,731–71,118,247, 117 genes, copy number 8–25 (broad region; genes not listed).
- chr20:44,841,925–45,176,544, 11 genes, copy number 5–16: PGBD4P2, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, PI3.
- chr20:49,903,391–62,861,822, 251 genes, copy number 5–22 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,219. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
